Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H8-01A from TCGA case TCGA-2Y-A9H8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 85.8 years (31,322 days).
Specimen TCGA-2Y-A9H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.a47bcfc5-409a-4b6d-b5c5-5e1f25a46b55.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2526a46-2e83-4888-a466-ed9883ac887d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 660; copy number 2: 19,767; copy number 3: 25,740; copy number 4: 5,372; copy number 5: 5,654; copy number 6: 1,152; copy number 7: 449; copy number 8: 982; copy number 15: 16; copy number 19: 4; copy number 53: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H8-01A-11D-A38W-01): tumor purity 0.66, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:23,690,104–24,088,051, 6 genes (within-gene range 0–2): ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,467 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–45,326,028, 684 genes, copy number 8 (broad region; genes not listed).
- chr5:58,198–43,280,850, 677 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:50,409,042–50,422,316, 1 gene, copy number 7: AC024405.1.
- chr20:48,624,252–53,827,297, 105 genes, copy number 8–53 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 660. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
